Somatic mutation profile of tumor specimen TCGA-EJ-7782-01A (aliquot TCGA-EJ-7782-01A-11D-2114-08) from TCGA case TCGA-EJ-7782, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.1 years (25,965 days).
Specimen TCGA-EJ-7782-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 687e187a-c95d-4977-83c1-0d452ff8a1bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7782-10A (Blood Derived Normal), aliquot TCGA-EJ-7782-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70e1cf8d-fd01-493c-a088-97c7eb2a0030

The open-access MAF lists 422 somatic variants for this specimen: 311 protein-altering or splice-affecting, 105 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 220, Silent 105, Frame Shift Del 49, Frame Shift Ins 14, Nonsense Mutation 12, Splice Site 8, Splice Region 5, In Frame Del 3, RNA 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459219194, COSV51645075; called by muse, mutect2
- SAG | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs201153410, CM981785; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACVR2A | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54025912; called by muse, mutect2, varscan2
- ADGRE5 | c.2305T>C p.Y769H (on ENST00000242786 / NM_078481.4; = p.Y676H on NM_001784.5) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54392545; called by muse, mutect2
- ADGRG2 | c.708G>A p.Q236= (on ENST00000379869 / NM_001079858.3; = p.Q233= on NM_005756.4) | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as COSV61340254; called by muse, mutect2, varscan2
- ADGRV1 | c.5944dup p.S1982Ffs*2 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | catalogued as rs1554081619; called by mutect2, pindel, varscan2
- ADRA1D | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.074); catalogued as COSV65241523; called by muse, mutect2
- AHSA1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs141659647; called by muse, mutect2, varscan2
- AKAP1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as rs781062994, COSV58471596; called by muse, mutect2, varscan2
- AKAP12 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs1450465809, COSV53573831; called by muse, mutect2
- AKAP9 | c.8293G>T p.A2765S (on ENST00000359028; = p.A2741S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs368001901, COSV62352435; ClinVar: likely benign; called by muse, mutect2, varscan2
- AKNA | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56313869; called by muse, mutect2, varscan2
- ALCAM | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60251546, COSV60253766; called by muse, mutect2, varscan2
- ALKBH1 | c.844A>G p.S282G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53660474; called by muse, mutect2, varscan2
- AMPD2 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV56649228; called by muse, mutect2, varscan2
- APBA1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV55232380; called by mutect2, varscan2
- APLP1 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs775640224, COSV55703996; called by muse, mutect2, varscan2
- APOO | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs369973145, COSV64870573; called by muse, mutect2, varscan2
- ARID3B | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1326379631, COSV60558366; called by muse, mutect2, varscan2
- ARSF | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1485629840, COSV63840374; called by muse, mutect2
- AXL | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs143593613; called by muse, mutect2, varscan2
- B3GALT5 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763469352, COSV58199771; called by muse, mutect2, varscan2
- BAZ1A | c.1590G>A p.W530* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV62411310; called by muse, mutect2, varscan2
- BCL9 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs587637107, COSV52347592; called by muse, mutect2, varscan2
- BCORL1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs749559990, COSV54401328; called by muse, mutect2, varscan2
- BICRAL | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.431); catalogued as rs575050000, COSV58407229; called by muse, mutect2, varscan2
- BRPF1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs779613609, COSV57406531; called by muse, mutect2, varscan2
- C3orf70 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as rs1359764993, COSV58589388; called by muse, mutect2
- C7orf57 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62363458; called by muse, mutect2, varscan2
- CABLES1 | c.913C>T p.R305W (on ENST00000256925 / NM_001100619.2; = p.R40W on NM_138375.2) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs767746873, COSV56935428; called by muse, mutect2, varscan2
- CAPZA1 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV54146373; called by muse, mutect2
- CC2D1A | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs752002689, COSV58784895; called by muse, mutect2, varscan2
- CCDC178 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV55785346; called by muse, mutect2, varscan2
- CCT3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs746245572, COSV55288933; called by muse, mutect2, varscan2
- CDC42BPG | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753194992, COSV61348331; called by muse, mutect2, varscan2
- CDH1 | c.745T>G p.L249V | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV55737108; called by muse, mutect2, varscan2
- CDH5 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.78); catalogued as COSV58518784; called by muse, mutect2, varscan2
- CENPT | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as rs923641449, COSV54651058; called by muse, mutect2, varscan2
- CERCAM | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs372180473; called by mutect2, varscan2
- CIRBP | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV58011617; called by muse, mutect2, varscan2
- CLCA1 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52329375; called by muse, mutect2, varscan2
- CLSTN1 | c.487G>A p.V163M (on ENST00000377298 / NM_001009566.3; = p.V153M on NM_014944.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs749102307, COSV63649693; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CNPY2 | c.395C>A p.T132N | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56264773; called by muse, mutect2, varscan2
- CNR1 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs764560714, COSV62986478; called by muse, mutect2, varscan2
- COL27A1 | c.5558A>G p.E1853G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61928776; called by muse, mutect2, varscan2
- COL6A6 | c.1802A>T p.D601V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV62031378; called by muse, mutect2
- COL7A1 | c.2586G>A p.T862= | Splice Region (SNP) | VAF 19/53 reads (36%) | catalogued as rs537416600, COSV60398785; called by muse, mutect2, varscan2
- COLGALT1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.684); catalogued as rs1230407785, COSV53107874; called by muse, mutect2
- COPZ2 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs755618049, COSV50058096; called by muse, mutect2
- CPEB1 | c.1392G>T p.K464N (on ENST00000617958; = p.K399N on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55620245; called by muse, mutect2
- CSE1L | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs376962564; called by muse, mutect2, varscan2
- CWF19L1 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62499561; called by muse, mutect2, varscan2
- DAGLA | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57198061; called by muse, mutect2
- DBH | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs745685569, COSV55041752; ClinVar: uncertain significance; called by mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX50 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV101007251, COSV65292950; called by muse, mutect2, varscan2
- DDX60L | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs570199575, COSV52710307; called by muse, mutect2, varscan2
- DGKD | c.3094-1G>T p.X1032_splice (on ENST00000264057 / NM_152879.3; = p.X988_splice on NM_003648.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/132 reads (6%) | catalogued as COSV51051092, COSV51071380; called by muse, mutect2
- DHX16 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV64564798; called by mutect2, varscan2
- DHX34 | c.3236C>T p.T1079M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538434908, COSV60896664; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH3 | c.4628A>G p.D1543G | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1183975424, COSV54536475; called by muse, mutect2, varscan2
- DNAH6 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV52872367; called by muse, mutect2, varscan2
- DNHD1 | c.13282T>A p.S4428T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54440208; called by muse, mutect2, varscan2
- DNMT3A | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs770568549, COSV53057587; called by muse, mutect2, varscan2
- DUSP1 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs770172254, COSV53320592; called by mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs775499198; called by mutect2, varscan2
- DYRK4 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368597301, COSV50541976; called by muse, mutect2, varscan2
- DZIP3 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.997); catalogued as rs767368068, COSV64312898; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as rs766700925; called by mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs770453803; called by mutect2, varscan2
- ENC1 | c.1277T>C p.M426T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as rs1337687383, COSV56630476; called by muse, mutect2, varscan2
- ENGASE | c.1117_1119del p.K373del | In Frame Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs1452093748; called by pindel, varscan2
- EP400 | c.4171G>A p.A1391T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV57779239; called by muse, mutect2, varscan2
- EPHA2 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868421931, COSV64454032; called by muse, mutect2, varscan2
- EPHX1 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV55302417; called by muse, mutect2, varscan2
- ESYT1 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.922); catalogued as rs763709224, COSV57274924; called by muse, mutect2, varscan2
- EVPL | c.1549T>G p.S517A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV56913511; called by muse, mutect2, varscan2
- FAM135B | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs1161174796, COSV52740077; called by muse, mutect2, varscan2
- FAM171A1 | c.2628G>A p.W876* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as COSV65317839; called by muse, mutect2, varscan2
- FDXR | c.811C>T p.R271C (on ENST00000293195 / NM_024417.5; = p.R277C on NM_004110.6) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571003894, COSV53115647; called by muse, mutect2, varscan2
- FGF5 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.498); catalogued as COSV56891130; called by muse, mutect2
- FOXG1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV57398219; called by muse, mutect2, varscan2
- FZD9 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.479); catalogued as rs782237874, COSV60670830; called by muse, mutect2, varscan2
- GABRA5 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs565602814, COSV59478566; called by muse, mutect2
- GAL3ST1 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV58893177; called by muse, mutect2
- GALNT3 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201078015, COSV67062084; called by muse, mutect2, varscan2
- GCC1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58463226; called by muse, mutect2, varscan2
- GCNA | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 122/183 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs747975519, COSV65467558, COSV65468428; called by muse, mutect2, varscan2
- GIGYF1 | c.2193+1G>A p.X731_splice | Splice Site (SNP) | VAF 32/82 reads (39%) | catalogued as rs1161181254, COSV51944545; called by muse, mutect2, varscan2
- GIGYF1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.724); catalogued as rs761541233, COSV51944564; called by muse, mutect2, varscan2
- GIMAP8 | c.1797T>G p.C599W | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV56232809; called by muse, mutect2, varscan2
- GPATCH1 | c.2413+1G>A p.X805_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV50120271; called by muse, mutect2, varscan2
- GPRIN3 | c.2105C>G p.A702G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60885622; called by muse, mutect2, varscan2
- GRK6 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs778598612, COSV62683485; called by muse, mutect2, varscan2
- HCFC2 | c.690G>C p.M230I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV57559278; called by muse, mutect2, varscan2
- HHIP | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs757831882, COSV56840989; called by muse, mutect2
- HIC1 | c.1621G>A p.G541R (on ENST00000322941 / NM_001098202.1; = p.G522R on NM_006497.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53962487, COSV53971560; called by muse, mutect2, varscan2
- HMCN1 | c.6180G>A p.Q2060= | Splice Region (SNP) | VAF 10/41 reads (24%) | catalogued as rs1487106900, COSV54919888, COSV54931998; called by muse, mutect2, varscan2
- HS3ST3B1 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100714424; called by muse, mutect2
- ICAM3 | c.668dup p.R224Afs*90 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | catalogued as rs759151580; called by mutect2, varscan2
- IGDCC3 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV60078762; called by muse, mutect2, varscan2
- IGHM | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.205); catalogued as rs759494596; called by muse, mutect2, varscan2
- IL12A | c.421-1G>A p.X141_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | catalogued as COSV59759745; called by muse, mutect2
- IL4R | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as rs533865105, COSV50155231; called by muse, mutect2, varscan2
- INHA | c.716G>A p.W239* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV54725387; called by muse, mutect2, varscan2
- IRAK2 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758996931, COSV56533750; called by muse, mutect2, varscan2
- ITPR1 | c.7205G>A p.C2402Y (on ENST00000354582; = p.C2347Y on NM_002222.7) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV56993097; called by muse, mutect2, varscan2
- ITPRIP | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1314976370, COSV53391747; called by muse, mutect2
- JADE3 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782380164, COSV54468501; called by muse, mutect2, varscan2
- KCNC1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV56394764; called by muse, mutect2, varscan2
- KCTD8 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.011); catalogued as rs1391410575, COSV63592732; called by muse, mutect2
- KHDRBS3 | c.752del p.P251Qfs*101 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | catalogued as rs776179021, COSV63421003; called by mutect2, pindel, varscan2
- KIF16B | c.2973G>T p.K991N | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV61710142; called by muse, mutect2, varscan2
- KIF2A | c.2012del p.I671Kfs*4 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as COSV66946255; called by mutect2, pindel, varscan2
- KLHDC1 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63779072; called by muse, mutect2, varscan2
- KLHL30 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1401795194, COSV59977240; called by muse, mutect2, varscan2
- KLHL36 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs765142128, COSV50721129; called by muse, mutect2, varscan2
- KMT2A | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as COSV63286137; called by muse, mutect2, varscan2
- KRT31 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs770513054, COSV52433752; called by muse, mutect2, varscan2
- KSR1 | c.2521G>A p.D841N (on ENST00000644974 / NM_001367810.1; = p.D726N on NM_014238.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs560099866, COSV52036033; called by muse, mutect2, varscan2
- LAD1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs754957644, COSV66212709, COSV66212941; called by muse, mutect2, varscan2
- LAMA4 | c.2612G>T p.R871L (on ENST00000230538 / NM_001105206.3; = p.R864L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV104369709, COSV57901471; called by muse, mutect2, varscan2
- LGI2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); catalogued as COSV66123494; called by muse, mutect2, varscan2
- LMTK3 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1387080802, COSV54314826; called by muse, mutect2, varscan2
- LRP3 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1197291462, COSV53505022; called by muse, mutect2, varscan2
- LRRC41 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs150782403; called by muse, mutect2, varscan2
- LRRC41 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.872); catalogued as rs185591715; called by muse, mutect2, varscan2
- LUC7L3 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 4/81 reads (5%) | catalogued as rs1567877144; called by muse, mutect2
- MACO1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs769171167, COSV65477394; called by muse, mutect2, varscan2
- MAGED1 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.941); catalogued as COSV58516038; called by muse, mutect2, varscan2
- MAN2A2 | c.2493del p.V832Cfs*82 | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | catalogued as rs755100936; called by mutect2, pindel
- MAN2C1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs149884810; called by muse, mutect2, varscan2
- MAPK1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53188095; called by muse, mutect2, varscan2
- MARK4 | c.1960dup p.R654Pfs*18 (on ENST00000262891 / NM_001199867.2; = p.G681Rfs*100 on NM_031417.4) | Frame Shift Ins (INS) | VAF 37/165 reads (22%) | catalogued as rs1568505994; called by mutect2, pindel, varscan2
- MASP1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs754485637, COSV56225321; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 39/65 reads (60%) | catalogued as rs746267361; called by mutect2, varscan2
- MCUB | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs781302533, COSV54461352; called by muse, mutect2, varscan2
- MED15 | c.2024C>T p.P675L (on ENST00000263205 / NM_001003891.3; = p.P635L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53031548; called by muse, mutect2, varscan2
- MEGF6 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); catalogued as COSV53892646; called by muse, mutect2
- MIGA1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs149790967; called by muse, mutect2, varscan2
- MNS1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs747360062, COSV53068173, COSV53069415; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV64056625; called by muse, mutect2, varscan2
- MSH2 | c.1613dup p.N538Kfs*3 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | catalogued as rs1558511092; called by mutect2, pindel, varscan2
- MUC16 | c.28688C>G p.T9563R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV67479832; called by muse, mutect2, varscan2
- MYBPHL | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs142341673; called by mutect2, varscan2
- MYL12B | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV52898903; called by muse, varscan2
- MYO9B | c.3451C>T p.R1151C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752037436, COSV68277334; called by muse, varscan2
- NAALADL2 | c.2288A>G p.Q763R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV71985812; called by muse, mutect2, varscan2
- NANP | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59160418; called by muse, mutect2, varscan2
- NASP | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV63113901; called by muse, mutect2, varscan2
- NCOR1 | c.5497del p.Q1833Rfs*17 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as COSV99248068; called by mutect2, pindel, varscan2
- NDST2 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs373342432, COSV55216455; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs747914168; called by mutect2, varscan2
- NEU4 | c.13C>T p.R5C (on ENST00000391969 / NM_001167602.3; = p.R17C on NM_080741.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs376890171, COSV57991279; called by muse, mutect2, varscan2
- NONO | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV52139060; called by muse, mutect2, varscan2
- NR3C2 | c.2810A>T p.D937V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV60995794; called by muse, mutect2, varscan2
- OBSCN | c.9994C>T p.R3332C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs375232996, COSV99471867; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs762005098; called by mutect2, varscan2
- OGFOD3 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780070620, COSV57342109; called by muse, mutect2, varscan2
- OR2T27 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61280561, COSV61282887; called by mutect2, varscan2
- OR3A1 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV60163530; called by muse, mutect2, varscan2
- OSBPL5 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284173268, COSV55143806; called by muse, mutect2, varscan2
- P4HA2 | c.836G>T p.R279M | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV51328104; called by muse, mutect2
- PAF1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as rs775209420, COSV55395258; called by muse, mutect2, varscan2
- PARD3B | c.3596A>G p.N1199S (on ENST00000406610 / NM_001302769.2; = p.N1130S on NM_057177.7) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV62520695; called by muse, mutect2, varscan2
- PCDHA2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV65365163; called by muse, mutect2
- PCDHA5 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as COSV65350531; called by muse, mutect2, varscan2
- PCDHGA2 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as rs754938154, COSV53989761; called by muse, mutect2, varscan2
- PCID2 | c.309-2A>G p.X103_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV55814390; called by muse, mutect2, varscan2
- PCSK4 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs773751308, COSV56300155; called by muse, mutect2, varscan2
- PDCL3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs777385726, COSV51809791; called by muse, mutect2, varscan2
- PDZRN3 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1204838316, COSV55208474; called by muse, mutect2, varscan2
- PFN2 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs763130284, COSV53523194; called by muse, mutect2
- PKD1 | c.11092G>A p.A3698T (on ENST00000262304 / NM_001009944.3; = p.A3697T on NM_000296.4) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV51914544, COSV51917542; called by muse, mutect2, varscan2
- PLBD2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs763737888, COSV55107972; called by muse, mutect2, varscan2
- PLCE1 | c.6472G>A p.V2158I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs200549010, COSV53361472; called by muse, mutect2, varscan2
- PLEKHG4 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58573913; called by muse, mutect2, varscan2
- PLEKHM1 | c.3101C>T p.A1034V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV69599224; called by muse, mutect2
- PPFIBP1 | c.1494del p.T499Pfs*46 (on ENST00000318304 / NM_177444.3; = p.T482Pfs*46 on NM_003622.4) | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as COSV57287766; called by mutect2, pindel, varscan2
- PPFIBP1 | c.1784A>G p.K595R (on ENST00000318304 / NM_177444.3; = p.K589R on NM_003622.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV57295518; called by muse, mutect2, varscan2
- PPHLN1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs144485658; called by muse, mutect2, varscan2
- PRG4 | c.3505T>C p.Y1169H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63356044; called by muse, mutect2, varscan2
- PRPS1L1 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.098); catalogued as COSV72649956; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs781858060; called by mutect2, varscan2
- PTGFRN | c.2078C>A p.S693Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67799085; called by muse, mutect2, varscan2
- PTGIR | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs201125347; called by muse, mutect2, varscan2
- RACGAP1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs759482511, COSV56700257; called by muse, mutect2, varscan2
- REC8 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1326732041, COSV61017439; called by muse, mutect2, varscan2
- RFC1 | c.2776C>T p.R926W (on ENST00000381897 / NM_001363496.2; = p.R925W on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752627380, COSV62900389; called by mutect2, varscan2
- RNF215 | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs749541052, COSV53176613; called by muse, varscan2
- RNF43 | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 33/110 reads (30%) | catalogued as rs371553160, COSV68460917; called by muse, mutect2, varscan2
- RPUSD1 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50099738, COSV50101333; called by muse, mutect2, varscan2
- RYR1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772767943, COSV62103784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as rs1490175548, COSV60066964; ClinVar: uncertain significance; called by muse, mutect2
- SCN8A | c.2509G>A p.V837M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV61987279; called by muse, varscan2
- SEMA3B | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1553706378, COSV57114642; called by muse, varscan2
- SEMA4G | c.339G>A p.T113= | Splice Region (SNP) | VAF 30/90 reads (33%) | catalogued as rs368885285; called by muse, mutect2, varscan2
- SENP7 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs151073689, COSV58615041; called by muse, mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs764980440, COSV58616367; called by mutect2, varscan2
- SFSWAP | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV55523967; called by muse, mutect2, varscan2
- SLC12A7 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53759708; called by muse, mutect2, varscan2
- SLC14A2 | c.1908-1G>A p.X636_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV54911550, COSV99674911; called by muse, mutect2, varscan2
- SLC38A10 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV55847345; called by muse, mutect2, varscan2
- SLC6A13 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374740428; called by muse, mutect2, varscan2
- SLC6A3 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755363921, COSV54366882; called by muse, mutect2, varscan2
- SLC9A5 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.227); catalogued as COSV55363485; called by muse, mutect2, varscan2
- SNX32 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs140929894, COSV57448860; called by muse, mutect2, varscan2
- SNX4 | c.1282A>G p.M428V | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52539315; called by muse, mutect2, varscan2
- SOGA3 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV64107655; called by muse, mutect2
- SPARC | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs150910656; called by muse, mutect2, varscan2
- SPECC1 | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs1420200225, COSV54962335; called by muse, mutect2, varscan2
- SPHK2 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as COSV55339631; called by muse, mutect2
- SPIDR | c.2155A>C p.S719R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.188); catalogued as rs566690509, COSV52383484; called by muse, mutect2, varscan2
- SPOP | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs1380705599, COSV61654924; called by muse, mutect2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 24/90 reads (27%) | catalogued as rs751748506; called by mutect2, varscan2
- STARD8 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1276005639, COSV52929552; called by muse, mutect2
- STAT6 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777634893, COSV55672700; called by muse, mutect2, varscan2
- STPG2 | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV54809510; called by mutect2, varscan2
- TAB1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53372305; called by muse, mutect2, varscan2
- TADA3 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs547844232, COSV57333916; called by muse, mutect2, varscan2
- TAF1 | c.3037T>C p.S1013P (on ENST00000373790 / NM_138923.4; = p.S1034P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52119792; called by muse, varscan2
- TASOR | c.1502G>A p.S501N (on ENST00000355628 / NM_001365636.2; = p.S105N on NM_015224.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62928805; called by muse, mutect2, varscan2
- TERF2 | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV54748263; called by muse, mutect2, varscan2
- TET1 | c.6071G>A p.R2024Q | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1169730805, COSV65385710; called by muse, mutect2, varscan2
- TFR2 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs763388776, COSV56155401; called by muse, mutect2, varscan2
- TGFB1I1 | c.461C>T p.A154V (on ENST00000394863 / NM_001042454.3; = p.A137V on NM_015927.4) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62358722; called by muse, mutect2
- THOC6 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV50187955; called by muse, mutect2, varscan2
- TIPARP | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55815032; called by muse, mutect2, varscan2
- TMEM128 | c.399C>T p.C133= (on ENST00000382753 / NM_001297552.2; = p.C109= on NM_032927.3) | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as rs1401919044, COSV54637561; called by muse, mutect2
- TMEM131 | c.2661G>C p.L887F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as COSV51781211; called by muse, mutect2, varscan2
- TMPRSS11B | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as rs376428535; called by muse, mutect2, varscan2
- TMX3 | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV55186467; called by muse, mutect2
- TNC | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as rs1415238602, COSV60787595; called by muse, mutect2, varscan2
- TNKS2 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as rs966364515, COSV65416173; called by muse, mutect2, varscan2
- TOP1MT | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239625, COSV61318887; called by muse, mutect2, varscan2
- TP53BP2 | c.3292G>A p.E1098K (on ENST00000343537 / NM_001031685.3; = p.E969K on NM_005426.2) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1483671107, COSV59070896; called by muse, varscan2
- TRAF7 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs778416555, COSV58216658; called by muse, mutect2, varscan2
- TRAPPC8 | c.866-2A>G p.X289_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV51974757; called by muse, mutect2, varscan2
- TRIM56 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs763483549, COSV60157200; called by muse, mutect2, varscan2
- TRIM62 | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52222494; called by muse, mutect2, varscan2
- TTF1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57506016; called by muse, mutect2, varscan2
- UBE2J2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1230826484; called by muse, mutect2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs749830910; called by mutect2, varscan2
- USP45 | c.2189A>G p.Y730C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59681697; called by muse, mutect2, varscan2
- VAC14 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs752526213, COSV55755670; called by muse, mutect2, varscan2
- VCPIP1 | c.1528T>C p.F510L | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV60049129; called by muse, mutect2, varscan2
- VWF | c.3017A>T p.D1006V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54627603; called by muse, mutect2, varscan2
- WDR37 | c.879del p.K294Sfs*4 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs1564508074; called by mutect2, pindel, varscan2
- XYLT2 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs150470450; called by muse, mutect2, varscan2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs761507279; called by mutect2, pindel, varscan2
- ZC3H6 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as rs1011242788, COSV59667467; called by muse, mutect2, varscan2
- ZNF19 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55508359; called by muse, mutect2, varscan2
- ZNF224 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs763079230, COSV61241842; called by muse, mutect2, varscan2
- ZNF37A | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs371302765; called by muse, mutect2, varscan2
- ZNF44 | c.1316G>A p.G439D (on ENST00000356109 / NM_001164276.2; = p.G391D on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61135851; called by muse, mutect2, varscan2
- ZNF71 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.441); catalogued as rs780191454, COSV60146551; called by muse, mutect2, varscan2
- ZNF75D | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs148068840, COSV66133126; called by muse, mutect2
- ABCA1 | c.5657_5663del p.S1886* | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- ACAA1 | c.1112del p.G371Vfs*5 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- ADRA1B | c.381del p.C128Afs*7 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.906del p.A303Qfs*18 (on ENST00000352432; = p.A303Pfs*56 on NM_001683.5) | Frame Shift Del (DEL) | VAF 45/145 reads (31%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.2470A>G p.K824E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ATXN7L2 | c.312del p.L106Sfs*23 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- CDK12 | c.4382del p.G1461Afs*38 (on ENST00000447079 / NM_016507.4; = p.G1452Afs*38 on NM_015083.3) | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- CGB5 | c.365del p.G122Vfs*7 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, varscan2
- CHSY3 | c.636del p.N213Tfs*29 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- CLTCL1 | c.756del p.P253Lfs*23 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); called by muse, mutect2
- DNAJB4 | c.618dup p.G207Rfs*16 | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- DNAJC2 | c.590dup p.N197Kfs*4 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- DNASE2B | c.938del p.K313Rfs*13 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.1923del p.K641Nfs*38 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- FSTL4 | c.1687del p.D563Tfs*11 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- GEMIN4 | c.985del p.E329Rfs*24 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- GTSE1 | c.2105del p.N702Mfs*13 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- ILVBL | c.633_634del p.V212Afs*143 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- KCNT1 | c.1135del p.R379Gfs*81 (on ENST00000488444; = p.R398Gfs*81 on NM_020822.3) | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- LMNA | c.539del p.K180Rfs*21 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- LPP | c.1003_1005del p.P335del | In Frame Del (DEL) | VAF 14/82 reads (17%) | called by pindel, varscan2
- MAP3K11 | c.2471del p.G824Afs*123 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- MXRA5 | c.7640dup p.I2548Dfs*51 | Frame Shift Ins (INS) | VAF 11/21 reads (52%) | called by mutect2, pindel, varscan2
- NDC80 | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NT5C3A | c.353dup p.L119Vfs*12 (on ENST00000610140 / NM_001374335.1; = p.L85Vfs*12 on NM_016489.13) | Frame Shift Ins (INS) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- OR5F1 | c.14dup p.N5Kfs*7 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- OXGR1 | c.461del p.C154Lfs*10 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- PAXBP1 | c.1108dup p.T370Nfs*3 | Frame Shift Ins (INS) | VAF 24/105 reads (23%) | called by mutect2, pindel, varscan2
- PDE8A | c.1505_1511del p.I502Nfs*11 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- PFN1 | c.207_209del p.K70del | In Frame Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- PUS3 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2
- RGS22 | c.2742del p.K914Nfs*18 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- SGIP1 | c.21dup p.R8Tfs*16 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- SIN3B | c.1102dup p.V368Gfs*23 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by pindel, varscan2
- SLC32A1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2
- SRGAP1 | c.168del p.A57Lfs*11 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- SRPX | c.677del p.P226Qfs*32 | Frame Shift Del (DEL) | VAF 28/51 reads (55%) | called by mutect2, pindel, varscan2
- STARD13 | c.2889del p.S964Qfs*4 (on ENST00000336934 / NM_001243476.3; = p.S846Qfs*4 on NM_052851.3) | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- SV2B | c.1755del p.F585Lfs*8 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- TCP1 | c.65-3_65-2del p.X22_splice | Splice Site (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- TOP2B | c.1136del p.N379Tfs*24 (on ENST00000264331 / NM_001330700.2; = p.N374Tfs*24 on NM_001068.3) | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- TTC37 | c.2592G>A p.W864* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- XPNPEP3 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- ZFC3H1 | c.5078del p.L1693Cfs*26 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.10062dup p.L3355Afs*76 | Frame Shift Ins (INS) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- ZNF41 | c.271del p.E91Kfs*35 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel, varscan2
- ZNF616 | c.2229del p.K743Nfs*23 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- ZNF791 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- AARS2 | c.2862G>A p.A954= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs142694525, COSV55116495; called by muse, mutect2, varscan2
- ADAMTS16 | c.2448C>T p.F816= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV56976343; called by muse, mutect2, varscan2
- ADAMTS6 | c.1104C>A p.P368= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV66862284; called by muse, mutect2, varscan2
- ADCY6 | c.1737G>A p.G579= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57169322; called by muse, mutect2, varscan2
- ADGRA2 | c.2571G>A p.A857= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs200971618, COSV55104637; called by muse, mutect2, varscan2
- AGAP3 | c.1872C>T p.N624= (on ENST00000622464; = p.N660= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as rs878873385, COSV68246479; called by muse, mutect2
- AHNAK | c.612C>T p.T204= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs368779297; called by muse, mutect2, varscan2
- ALX3 | c.912C>T p.P304= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs753787190, COSV63928964; called by muse, mutect2, varscan2
- ANKMY1 | c.279C>T p.D93= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs147984796; called by muse, mutect2, varscan2
- ANO1 | c.2613G>A p.P871= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs752920987, COSV62445948; called by muse, mutect2, varscan2
- ARHGEF19 | c.843C>T p.N281= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV54617620; called by muse, mutect2, varscan2
- ATP2B2 | c.2163C>T p.G721= (on ENST00000352432; = p.G687= on NM_001683.5) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs758683952, COSV59492411; called by muse, mutect2, varscan2
- ATP2C2 | c.234G>A p.S78= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs759777409, COSV52298812; called by muse, mutect2, varscan2
- ATP5PD | c.474T>C p.I158= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV56903180; called by muse, mutect2, varscan2
- BMS1 | c.624G>A p.T208= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs1384904704, COSV65734009; called by muse, mutect2, varscan2
- BTAF1 | c.4002G>A p.P1334= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs757434809, COSV56429485; called by muse, mutect2, varscan2
- C1orf43 | c.744A>T p.T248= (on ENST00000368521 / NM_001297718.2; = p.T214= on NM_015449.4) | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV62966589; called by muse, mutect2, varscan2
- C3orf20 | c.1155C>T p.F385= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as rs767835959, COSV53782675; called by muse, mutect2, varscan2
- CACNA2D3 | c.2319C>T p.A773= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs373671539; called by muse, mutect2, varscan2
- CATSPERE | c.1185G>A p.E395= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV63679983; called by muse, mutect2
- CENPE | c.3999G>A p.L1333= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs745496238, COSV54384874; called by muse, mutect2, varscan2
- COL27A1 | c.522C>T p.C174= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1350972747, COSV61921603; called by muse, mutect2, varscan2
- COTL1 | c.324C>T p.F108= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs577103781, COSV52289857; called by muse, mutect2, varscan2
- CP | c.1161C>A p.P387= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV52832252; called by muse, mutect2, varscan2
- CTCFL | c.225C>T p.S75= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs755019448, COSV54776796; called by muse, mutect2, varscan2
- DICER1 | c.3237C>T p.G1079= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs764827361, COSV58624336; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DOT1L | c.3012C>T p.H1004= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV67111745; called by muse, mutect2, varscan2
- DUS1L | c.1383A>C p.P461= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV57650455; called by muse, mutect2, varscan2
- EIF2B1 | c.813G>A p.P271= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs748761790, COSV53016848; ClinVar: likely benign; called by muse, mutect2, varscan2
- FHOD1 | c.2889C>T p.Y963= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs935221389, COSV50764305; called by muse, mutect2, varscan2
- GAREM1 | c.1737C>T p.S579= (on ENST00000269209 / NM_001242409.2; = p.I578= on NM_022751.3) | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs373713186; called by muse, mutect2, varscan2
- GMIP | c.921G>T p.L307= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV52553881, COSV52558313; called by muse, mutect2, varscan2
- GMPPB | c.756C>T p.G252= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV57539389; called by muse, mutect2, varscan2
- GPC6 | c.1242G>A p.A414= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs1378616963, COSV65523086; called by muse, mutect2
- GPX4 | c.510C>T p.I170= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs745797291, COSV62318675; called by muse, mutect2, varscan2
- HUWE1 | c.7140C>T p.D2380= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV53334684; called by muse, mutect2
- ICMT | c.231C>T p.F77= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1457847881, COSV59474040; called by muse, mutect2, varscan2
- IL2RB | c.1491G>A p.G497= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV53427587; called by muse, mutect2, varscan2
- JAKMIP3 | c.2346C>A p.V782= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV53826406; called by muse, mutect2
- KMT2D | c.2133G>A p.P711= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs1257302144, COSV56456732; called by muse, mutect2, varscan2
- LRRN3 | c.690C>T p.N230= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs146797927; called by muse, mutect2
- MCM6 | c.1968C>A p.I656= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs773560866, COSV51467933; called by muse, mutect2, varscan2
- MDGA2 | c.1623A>G p.K541= (on ENST00000399232 / NM_001113498.2; = p.K243= on NM_182830.4) | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV62104087; called by muse, mutect2
- MEAK7 | c.1230G>A p.A410= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs776161259, COSV59144882; called by muse, mutect2, varscan2
- MEX3B | c.873G>A p.S291= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1196103290, COSV61662920; called by muse, mutect2, varscan2
- MIOS | c.2523T>C p.S841= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs779170837, COSV60769763; called by muse, mutect2, varscan2
- MSI1 | c.678C>A p.T226= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV57457155; called by muse, mutect2, varscan2
- MTG2 | c.450C>T p.G150= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs950173255, COSV63693774; called by muse, mutect2, varscan2
- MTMR3 | c.2814C>A p.A938= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV60306827; called by muse, mutect2, varscan2
- MYH2 | c.429C>T p.Y143= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV55443366; called by muse, mutect2, varscan2
- NBEA | c.5175G>A p.T1725= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs760852834, COSV59804086; called by muse, mutect2, varscan2
- NCSTN | c.147C>A p.P49= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54106132; called by muse, mutect2, varscan2
- NEURL4 | c.3354C>T p.G1118= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV59751849; called by muse, mutect2
- NIM1K | c.879C>T p.H293= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV58142190; called by muse, mutect2, varscan2
- NISCH | c.4236C>T p.R1412= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs772295242, COSV58740124; called by muse, mutect2, varscan2
- NPAT | c.66T>C p.S22= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV53719747; called by muse, mutect2, varscan2
- NPNT | c.324C>T p.Y108= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1372166224, COSV59753459, COSV59754882; called by muse, mutect2, varscan2
- NSFL1C | c.132C>T p.D44= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs191322139, COSV53792185; called by muse, mutect2, varscan2
- NUF2 | c.1023C>T p.F341= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV54845206; called by muse, mutect2, varscan2
- OR2M2 | c.681C>T p.H227= | Silent (SNP) | VAF 13/262 reads (5%) | catalogued as COSV62898928; called by muse, mutect2
- OR4E2 | c.66G>A p.V22= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV57732041; called by muse, mutect2, varscan2
- OR5M11 | c.543G>A p.P181= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs979783807, COSV73141942; called by muse, mutect2, varscan2
- OTUD4 | c.3336G>A p.Q1112= (on ENST00000447906 / NM_001366057.1; = p.Q1047= on NM_001102653.1) | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV71382070; called by muse, mutect2
- OVOL2 | c.714G>A p.P238= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs376394167, COSV99602311; called by muse, mutect2, varscan2
- PABPC3 | c.1761A>G p.E587= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV55803066, COSV99880320; called by muse, mutect2
- PCDHA12 | c.1611G>A p.A537= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs1554169304, COSV56526373; called by muse, mutect2, varscan2
- PCDHB1 | c.789G>A p.T263= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs782019630, COSV60632205; called by muse, mutect2, varscan2
- PHC2 | c.1470A>G p.S490= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99930607; called by muse, mutect2
- PIK3CA | c.3081C>A p.A1027= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV55957231; called by muse, mutect2, varscan2
- PLOD1 | c.813C>T p.D271= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs373471550; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PLXNA2 | c.735C>T p.Y245= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as rs779978151, COSV65442828; called by muse, mutect2, varscan2
- PNMA2 | c.837G>A p.A279= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV72908575; called by muse, mutect2, varscan2
- POLG2 | c.240T>C p.S80= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV56750335; called by muse, mutect2, varscan2
- POLR2B | c.1495A>C p.R499= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs899831783, COSV58901715; called by muse, mutect2, varscan2
- POTEA | c.207C>G p.L69= | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- PPP1R16A | c.249C>T p.D83= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV52954027; called by muse, mutect2, varscan2
- PRDM10 | c.1491G>A p.T497= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV58803221; called by muse, mutect2, varscan2
- PTPN3 | c.2289C>T p.D763= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs757229115, COSV52708419; called by muse, mutect2, varscan2
- PYCR2 | c.675C>T p.C225= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV59525208; called by muse, mutect2, varscan2
- RAB39B | c.414C>T p.A138= | Silent (SNP) | VAF 48/74 reads (65%) | catalogued as COSV65624385, COSV65624954; called by muse, mutect2, varscan2
- RAB9A | c.249C>T p.C83= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV54611026; called by muse, mutect2, varscan2
- RALGPS1 | c.792C>T p.S264= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs940092485, COSV52227310; called by muse, mutect2, varscan2
- RFFL | c.642C>T p.S214= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1412389691, COSV52072964; called by muse, mutect2, varscan2
- RPAP2 | c.825C>T p.G275= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs749859801, COSV72509253; called by muse, mutect2
- S100P | c.27C>T p.G9= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56399078; called by muse, mutect2, varscan2
- SCARF1 | c.1086C>A p.S362= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV53959979, COSV53961723; called by muse, mutect2, varscan2
- SLC16A7 | c.159T>C p.T53= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV53897365; called by muse, mutect2, varscan2
- SLC38A11 | c.57T>C p.V19= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV58055016; called by muse, mutect2, varscan2
- SLC7A2 | c.22C>T p.L8= (on ENST00000494857 / NM_001370338.1; = p.L48= on NM_003046.6) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1333235008, COSV50263252; called by muse, mutect2, varscan2
- SLCO5A1 | c.690G>A p.S230= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV52663753; called by muse, mutect2, varscan2
- SLITRK4 | c.2256C>T p.S752= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs782353906, COSV62025258; called by muse, mutect2, varscan2
- SMPDL3B | c.1071C>T p.L357= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs373190969; called by muse, mutect2, varscan2
- SRPK3 | c.1584C>T p.Y528= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs373971097, COSV54206986; called by muse, mutect2
- STK31 | c.2475T>A p.P825= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV63457989; called by muse, mutect2
- SURF6 | c.690G>A p.P230= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs782134230, COSV64395667; called by muse, mutect2, varscan2
- TAS1R1 | c.549C>A p.P183= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV60229271; called by muse, mutect2, varscan2
- TCIM | c.222G>A p.V74= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as rs976265807; called by muse, mutect2
- TRIM62 | c.537C>T p.G179= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs781609175, COSV52222507; called by muse, mutect2, varscan2
- USP6NL | c.1221G>A p.A407= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs577831766, COSV53209431; called by muse, varscan2
- VILL | c.462C>A p.S154= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV52183103, COSV52186521; called by muse, mutect2
- VIT | c.1374G>A p.S458= (on ENST00000389975 / NM_001177969.1; = p.S473= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs746829069, COSV64898010; called by muse, mutect2, varscan2
- VPS13D | c.11718C>T p.T3906= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs376413956; called by muse, mutect2, varscan2
- ZBTB2 | c.1530C>T p.T510= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs377600897; called by muse, mutect2, varscan2
- ZNF750 | c.1692G>A p.P564= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs758825441, COSV53960279; called by muse, mutect2, varscan2
- ZNF777 | c.1315C>T p.L439= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs745769608, COSV56099024; called by muse, mutect2, varscan2
- BTN2A3P | n.1186del | RNA (DEL) | VAF 30/78 reads (38%) | catalogued as rs553174245; called by mutect2, varscan2
- CADPS | c.2582-917A>G | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV51891894; called by muse, mutect2, varscan2
- CMTM1 | c.81+63C>T | Intron (SNP) | VAF 6/67 reads (9%) | catalogued as rs1053217799, COSV50451528; called by muse, mutect2
- LARS2 | c.*576G>T | 3'UTR (SNP) | VAF 7/29 reads (24%) | catalogued as COSV55526139; called by muse, mutect2, varscan2
- RPL26P30 | n.640G>A | RNA (SNP) | VAF 31/135 reads (23%) | catalogued as rs771604954; called by muse, mutect2, varscan2
- STAG3L2 | n.447G>A | RNA (SNP) | VAF 62/243 reads (26%) | catalogued as rs782798788; called by muse, mutect2, varscan2
